Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4TC, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4TC-01A (Primary Tumor).

HPAIA Discrepancy		☒

Surgical Pathology

Requested By:

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 J1 K1 K2 B1 C1 C2 C3 C4 C5 C6 D1 D2 E1 F1
F2 G1 H1 H2 H3 H4 H5 H6 I1
Right middle/lower lobes lung (295.0 grams), tissue from right lung
fissure (0.4 x 0.4 x 0.3 cm), station 2R lymph nodes, station 4R
lymph nodes (2 sets), station 7 lymph nodes (2 sets), station 9R
lymph nodes, station 10R lymph nodes, bronchus intermedius lymph
nodes, right upper lobe lung superior pulmonary vein lymph node.

DIAGNOSIS:

Lung, right middle and lower lobes, bilobectomy: Invasive grade 4
(of 4) adenocarcinoma, forming a well-circumscribed 1.6 x 1.5 x 1.5
cm cm subpleural mass. visceral pleural invasion is absent.
Angiolymphatic invasion is present. The bronchial margin is
negative for tumor (by 8.2 cm). with available surgical material,
AJCCpT1pN2.

Lung, right fissure, biopsy: Grade 4 (of 4) adenocarcinoma.

Lymph nodes, intrapulmonary/hilar, excision:

- Metastatic adenocarcinoma is identified in multiple (3 of 4) intrapulmonary peribronchial lymph nodes. Extranodal extension is identified and extends through the major fissure.
- No tumor is identified in a single (1) right hilar (station 10R) lymph node.

Lymph nodes, mediastinal, excision:

- Metastatic adenocarcinoma is identified in a single (1 of 21) right lower paratracheal (station 4R) lymph node.
- Metastatic adenocarcinoma is identified in a single (1 of 18) subcarinal (station 7) lymph node.
- No tumor is identified in multiple (5) right upper paratracheal (station 2R) lymph nodes.
- No tumor is identified in multiple (2) right pulmonary ligament (station 9R) lymph nodes.

Lymph nodes, bronchus intermedius, excision: Metastatic adenocarcinoma is identified in a single (1 of 3) bronchus intermedius lymph nodes.

Lymph nodes, right upper lobe lung superior pulmonary vein, excision: A single (1) right upper lobe lung superior pulmonary vein lymph node is negative for tumor.

ICD-O-3

Adenocarcinoma, NOS 8140/3

Path: Site: lung, NOS C34.9

CQCF: lung, @middle lobe C34.2

lu
10/29/12

Source: NCI Genomic Data Commons file cd4f2a70-48b2-4c9f-b4e0-a8b8076362b4 (TCGA-MP-A4TC.556F6F07-52C6-4FFA-AB6B-46FD9614EB0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).